Somatic mutation profile of tumor specimen MMRF_2305_1_BM_CD138pos (aliquot MMRF_2305_1_BM_CD138pos_T1_KHS5U_L11055) from MMRF case MMRF_2305, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.3 years (24,948 days).
Specimen MMRF_2305_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2340f05f-4cd7-42fd-9330-4e89194a88e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2305_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2305_1_PB_WBC_C2_KHS5U_L11056; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13af08a-a62f-4551-ba69-a4be35394c98

The open-access MAF lists 81 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Intron 10, Silent 8, 3'Flank 5, 5'Flank 2, Frame Shift Del 2, Splice Site 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs901905563; called by muse, mutect2, varscan2
- CCDC141 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55384707; called by muse, mutect2, varscan2
- CCND1 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772785280; called by muse, varscan2
- EWSR1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 10/227 reads (4%) | catalogued as rs1403104724, COSV58423098; called by muse, mutect2
- G3BP1 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs968398367; called by muse, mutect2, varscan2
- KRI1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1481432949; called by muse, mutect2, varscan2
- MAB21L3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV65674605; called by muse, mutect2, varscan2
- PHB2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs1555151929; called by muse, mutect2, varscan2
- RP1 | c.2508G>A p.M836I | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as rs1412005334; called by muse, mutect2
- SLC4A1 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs993990444; called by muse, mutect2, varscan2
- TRIO | c.7496C>A p.S2499Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59991115; called by muse, mutect2, varscan2
- TYRO3 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs946916314, COSV55481143; called by muse, mutect2, varscan2
- VCAN | c.3926C>T p.T1309M | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149651541; called by muse, mutect2, varscan2
- ATG2A | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CCND1 | c.91A>C p.M31L | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- COL3A1 | c.2947C>A p.P983T | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRBN | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- FZD6 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HERC6 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGHG1 | c.635del p.P212Qfs*30 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- NCOR1 | c.7097_7101del p.T2366Rfs*19 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | called by mutect2, pindel
- NELL1 | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- NSD1 | c.4641+2T>G p.X1547_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- OTOF | c.1252C>G p.R418G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- PGAM5 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- PGLYRP3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.284); called by muse, mutect2
- PSMD1 | c.1556T>G p.V519G | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RYR2 | c.12619T>C p.S4207P | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SEMA3A | c.912T>A p.H304Q | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SPATA31E1 | c.3693C>A p.S1231R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2
- TSC22D2 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- VCAN | c.8327A>C p.H2776P | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF480 | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CRACD | c.1782C>T p.T594= | Silent (SNP) | VAF 22/327 reads (7%) | catalogued as rs755276544; called by muse, mutect2
- DSC1 | c.1698T>C p.H566= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- DTX1 | c.573C>T p.P191= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs1262913778; called by muse, mutect2
- MAPKAP1 | c.531C>T p.I177= | Silent (SNP) | VAF 81/716 reads (11%) | catalogued as rs781447341, COSV56375096; called by muse, mutect2, varscan2
- NBEA | c.3003A>C p.R1001= | Silent (SNP) | VAF 67/448 reads (15%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1662C>T p.S554= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- THBS1 | c.246G>C p.V82= | Silent (SNP) | VAF 21/330 reads (6%) | called by muse, mutect2
- XAB2 | c.2370C>T p.R790= | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as rs1440297065, COSV50341242; called by muse, mutect2, varscan2
- AC008592.1 | chr5:95859837 C>G | 5'Flank (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- AFF1 | c.*3780T>A | 3'UTR (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- ATM | c.*3267A>T | 3'UTR (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- BCL11B | c.*4311G>T | 3'UTR (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- BORCS5 | c.*228C>G | 3'UTR (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- C16orf70 | c.355+35G>A | Intron (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- CCDC24 | c.303-19T>C | Intron (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- CCT6P3 | chr7:65078677 G>A | 3'Flank (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- CHDH | c.*261C>G | 3'UTR (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- CST7 | c.-45C>T | 5'UTR (SNP) | VAF 27/168 reads (16%) | catalogued as rs1568803477; called by muse, mutect2, varscan2
- DBN1 | c.86+1174_86+1185del | Intron (DEL) | VAF 29/324 reads (9%) | called by mutect2, pindel
- EHD1 | c.*2317G>C | 3'UTR (SNP) | VAF 108/618 reads (17%) | called by muse, mutect2, varscan2
- FGL1 | chr8:17896259 C>G | 5'Flank (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- GCFC2 | c.*1466T>C | 3'UTR (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- HRH2 | chr5:175686116 A>G | 3'Flank (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- IGLC2 | c.*104A>C | 3'UTR (SNP) | VAF 14/239 reads (6%) | called by muse, mutect2
- ING3 | c.267+821A>G | Intron (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- IQSEC3 | c.1992-52C>T | Intron (SNP) | VAF 21/169 reads (12%) | catalogued as rs1215305256; called by muse, mutect2, varscan2
- KAT2B | c.*145C>T | 3'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- KCNU1 | c.2010-16543C>G | Intron (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109966936 T>C | 3'Flank (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- LTO1 | c.*944T>C | 3'UTR (SNP) | VAF 51/269 reads (19%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92912G>T | Intron (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- MOB1B | c.*3007A>G | 3'UTR (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- MRAP2 | c.*953A>G | 3'UTR (SNP) | VAF 12/218 reads (6%) | catalogued as rs905669388; called by muse, mutect2
- NCBP1 | c.2259+341C>T | Intron (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- OR8J1 | c.*63T>C | 3'UTR (SNP) | VAF 30/200 reads (15%) | catalogued as rs548575754; called by muse, mutect2, varscan2
- PCDHB1 | c.*94A>T | 3'UTR (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2
- PRKAG2 | c.1234-23G>A | Intron (SNP) | VAF 45/262 reads (17%) | catalogued as rs201375674; called by muse, mutect2, varscan2
- PXYLP1 | c.*1644A>G | 3'UTR (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- SCRN2 | c.1-42T>A | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- SLC12A5 | chr20:46058499 C>G | 3'Flank (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- SLC43A3 | c.*341C>T | 3'UTR (SNP) | VAF 24/147 reads (16%) | catalogued as rs141322642; called by muse, mutect2, varscan2
- SOX6 | chr11:15971917 G>A | 3'Flank (SNP) | VAF 34/275 reads (12%) | called by muse, mutect2, varscan2
- SYT4 | c.*1915G>A | 3'UTR (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- TMEM108 | c.*776A>G | 3'UTR (SNP) | VAF 75/440 reads (17%) | called by muse, mutect2, varscan2
- TMEM47 | c.*3236G>A | 3'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as rs755517796; called by muse, mutect2, varscan2
- TMEM47 | c.*1615A>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- WDFY1 | c.*1056C>G | 3'UTR (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- ZNRF3 | c.*1880A>G | 3'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
